Somatic mutation profile of tumor specimen MP2PRT-PASMRY-TMP1-A (aliquot MP2PRT-PASMRY-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASMRY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,280 days).
Specimen MP2PRT-PASMRY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34ca13f1-1993-4b6d-ab85-d64d73b39a05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMRY-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMRY-NB1-B-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69deb920-19fe-4925-a8a6-bdebb4d9b189

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 19/491 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57322473; called by muse, mutect2
- SCARA3 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 162/371 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs150039603; called by muse, mutect2, varscan2
- WDR25 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 155/367 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs377508410; called by muse, mutect2, varscan2
- CA11 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 141/334 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CREBBP | c.3490G>A p.A1164T | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SPI1 | c.209_210insGGGGC p.F70Lfs*118 | Frame Shift Ins (INS) | VAF 62/510 reads (12%) | called by mutect2, pindel, varscan2
- GNA13 | c.15G>A p.L5= | Silent (SNP) | VAF 138/297 reads (46%) | called by muse, mutect2, varscan2
- KANK3 | c.798C>T p.S266= | Silent (SNP) | VAF 268/611 reads (44%) | called by muse, mutect2, varscan2
- TSC2 | c.4608G>A p.Q1536= | Silent (SNP) | VAF 90/356 reads (25%) | called by muse, mutect2, varscan2
